Somatic mutation profile of tumor specimen TCGA-FF-8062-01A (aliquot TCGA-FF-8062-01A-11D-2210-10) from TCGA case TCGA-FF-8062, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 60.1 years (21,959 days).
Specimen TCGA-FF-8062-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9deafe17-5df8-43bf-a5c0-a717f050e039.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8062-10A (Blood Derived Normal), aliquot TCGA-FF-8062-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f166e9-8a60-4c21-b2be-a320ab4aca4f

The open-access MAF lists 147 somatic variants for this specimen: 113 protein-altering or splice-affecting, 29 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 29, Nonsense Mutation 8, Frame Shift Del 7, Splice Site 3, Intron 3, Frame Shift Ins 2, 5'UTR 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.20T>C p.L7S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100837677, COSV62564278, COSV62565442; called by muse, varscan2
- MAP2K1 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 56/111 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 34/153 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs3730271, CM086899, CM137735, COSV52577994, COSV52586258; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV57664846; called by muse, mutect2, varscan2
- ATP2C2 | c.1164A>T p.E388D | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1413631261; called by muse, mutect2, varscan2
- B2M | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV62565612; called by muse, varscan2
- CCR6 | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | catalogued as COSV59475794; called by muse, mutect2, varscan2
- CD93 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs140540216, COSV55664977; called by muse, mutect2, varscan2
- CDH10 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs140810299; called by muse, mutect2, varscan2
- CDH16 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1243257608; called by muse, mutect2, varscan2
- CFAP47 | c.4045C>T p.L1349F | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.958); catalogued as rs1402760380; called by muse, mutect2, varscan2
- CHD8 | c.3977G>A p.C1326Y (on ENST00000646647 / NM_001170629.2; = p.C1047Y on NM_020920.4) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455284686, COSV63219455; called by muse, mutect2, varscan2
- COASY | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs367865615; called by muse, mutect2, varscan2
- COL11A1 | c.4102G>T p.A1368S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757857147; called by muse, mutect2, varscan2
- DDX3X | c.1699C>T p.P567S (on ENST00000399959; = p.P568S on NM_001356.5) | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863657; called by muse, mutect2
- EPHA6 | c.2297G>A p.R766Q (on ENST00000389672 / NM_001080448.3; = p.R158Q on NM_173655.4) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs751817193, COSV67567287; called by muse, mutect2, varscan2
- FLNC | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs993226627, COSV57967250; called by muse, mutect2, varscan2
- HECW2 | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 54/197 reads (27%) | catalogued as COSV53658555; called by muse, mutect2, varscan2
- IGKJ5 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs188703994; called by muse, varscan2
- IGKV3-15 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 144/1224 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1240281110; called by muse, varscan2
- IGLV3-1 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs372924773; called by muse, varscan2
- IGLV4-60 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1568964491; called by muse, mutect2, varscan2
- KCNK10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs975992605, COSV100068530, COSV56638780; called by muse, mutect2, varscan2
- KIAA2012 | c.3170A>G p.E1057G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); catalogued as rs763699918; called by muse, mutect2, varscan2
- KLHL6 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.944); catalogued as COSV58064346, COSV58064976; called by muse, mutect2, varscan2
- LACTB | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.12); catalogued as rs556545187; called by muse, mutect2, varscan2
- LAMA4 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs1554358711, COSV99683695; called by muse, mutect2, varscan2
- MAPK7 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1183830169; called by muse, mutect2, varscan2
- OR5H6 | c.141C>A p.F47L (on ENST00000642105; = p.F31L on NM_001005479.2) | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67351102; called by muse, mutect2, varscan2
- OR5W2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs893612926, COSV60618697; called by muse, mutect2, varscan2
- PCDH9 | c.3442T>G p.L1148V (on ENST00000377865 / NM_203487.3; = p.L1114V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.301); catalogued as COSV60586854; called by muse, mutect2, varscan2
- PDE5A | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs142017762; called by muse, mutect2, varscan2
- RAF1 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50104415, COSV50105010, COSV99312730; called by muse, mutect2, varscan2
- RALYL | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as rs745691095, COSV72818739; called by muse, mutect2, varscan2
- SEMA3A | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV54883776; called by muse, mutect2, varscan2
- TACR3 | c.1192A>G p.S398G | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1333780583; called by muse, mutect2, varscan2
- TDRD10 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 5/149 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1328749322; called by muse, mutect2
- THRB | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV62842575; called by muse, mutect2, varscan2
- TIAM2 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1490827882, COSV59692289; called by muse, varscan2
- TMEM200A | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759940770, COSV51649430; called by muse, mutect2, varscan2
- TMSB4X | c.117G>C p.K39N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV101020336; called by muse, mutect2, varscan2
- TTLL4 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs778775604; called by muse, mutect2, varscan2
- ZFX | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58447480; called by muse, mutect2, varscan2
- ZNF423 | c.2743C>T p.R915W (on ENST00000563137 / NM_001379286.1; = p.R907W on NM_015069.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs544721667, COSV99283362; called by muse, mutect2, varscan2
- AGK | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- ALAS2 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.11719T>G p.Y3907D | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARHGAP22 | c.1906T>C p.S636P | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ARHGAP23 | c.3292A>G p.S1098G | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ARHGEF26 | c.1090dup p.M364Nfs*9 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ARHGEF6 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- ATP4A | c.2291A>C p.D764A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BRIP1 | c.3725A>C p.K1242T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- BTBD7 | c.2797dup p.T933Nfs*15 | Frame Shift Ins (INS) | VAF 81/362 reads (22%) | called by mutect2, pindel, varscan2
- CAMK4 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CKAP5 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CPXM1 | c.1907T>A p.L636H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYYR1 | c.73+1G>A p.X25_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- DDX39B | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX52 | c.1635T>G p.F545L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.4669G>A p.A1557T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DSEL | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, varscan2
- FAM83D | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2
- FAU | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- FBXL7 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- GH2 | c.553A>T p.N185Y | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK4 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HS3ST4 | c.1271T>G p.V424G | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG1 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, varscan2
- IGKV1D-8 | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- JADE3 | c.1217A>G p.E406G | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LIMS1 | c.864-1G>A p.X288_splice | Splice Site (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- LMO7 | c.3888C>A p.D1296E (on ENST00000357063; = p.D977E on NM_005358.5) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MAGEC1 | c.2282A>G p.E761G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MAGI2 | c.1230A>C p.K410N | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUSK | c.730del p.T244Pfs*18 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- NBEA | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOVA2 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- OR5AK2 | c.533del p.F178Sfs*30 | Frame Shift Del (DEL) | VAF 43/292 reads (15%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.79T>C p.S27P (on ENST00000259318 / NM_001136562.3; = p.S258P on NM_007203.5) | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCLO | c.3635del p.K1212Sfs*9 | Frame Shift Del (DEL) | VAF 51/250 reads (20%) | called by mutect2, pindel, varscan2
- PRRC2C | c.8185_8186del p.Q2729Vfs*21 (on ENST00000367742; = p.Q2727Vfs*21 on NM_015172.4) | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by pindel, varscan2
- RBM14 | c.1293_1295dup p.Y432dup | In Frame Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- RBM27 | c.1080T>G p.S360R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMS3 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RBMS3 | c.888+1G>T p.X296_splice | Splice Site (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- RHBDF1 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RNGTT | c.1237A>T p.K413* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- SGK1 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); called by muse, varscan2
- SLC6A6 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SMG1 | c.7747C>T p.L2583F | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SP140 | c.300T>G p.S100R | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SSX2IP | c.807A>C p.Q269H | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- STK17A | c.1242C>G p.Y414* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- SULF1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SYT14 | c.1548G>C p.M516I | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TET2 | c.3151_3160del p.Q1051* | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | called by mutect2, pindel, varscan2
- TET2 | c.3964del p.L1322Wfs*41 | Frame Shift Del (DEL) | VAF 47/240 reads (20%) | called by mutect2, pindel, varscan2
- TMC5 | c.2530T>C p.S844P (on ENST00000396229 / NM_001105248.1; = p.S598P on NM_024780.5) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM184C | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TMEM255B | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- TNFRSF14 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM38 | c.1179T>A p.Y393* | Nonsense Mutation (SNP) | VAF 56/159 reads (35%) | called by muse, mutect2, varscan2
- ULK3 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.072); called by muse, mutect2
- UXS1 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA7 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- XKRX | c.303T>A p.F101L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ZBTB12 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZBTB2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZEB2 | c.7_22del p.Q3Mfs*19 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.10085A>T p.D3362V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL8A | c.22C>T p.L8= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- CCDC92 | c.177C>T p.C59= | Silent (SNP) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- DCPS | c.528G>C p.V176= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- FHOD3 | c.3987C>T p.P1329= (on ENST00000359247 / NM_001281739.3; = p.P1346= on NM_025135.5) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs200423151, COSV57163918, COSV57164848; called by muse, mutect2, varscan2
- GAREM1 | c.1701C>T p.T567= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as rs1335085342; called by muse, mutect2, varscan2
- H1-1 | c.630G>A p.A210= | Silent (SNP) | VAF 97/233 reads (42%) | called by muse, mutect2, varscan2
- HECTD4 | c.10701C>T p.S3567= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- IGLL5 | c.132A>T p.A44= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs559053132, COSV73250410, COSV73251264; called by muse, varscan2
- IRS4 | c.3408G>A p.A1136= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- KLK6 | c.300C>T p.A100= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs772152972, COSV100037864; called by muse, mutect2, varscan2
- LTBP1 | c.4743G>C p.V1581= (on ENST00000404816 / NM_206943.4; = p.V1255= on NM_000627.4) | Silent (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- MAPK10 | c.522G>A p.R174= (on ENST00000359221 / NM_001351625.2; = p.R212= on NM_002753.5) | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as COSV100174755; called by muse, mutect2, varscan2
- MSMP | c.174T>C p.S58= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs1255011015; called by muse, mutect2, varscan2
- MTUS2 | c.3357C>T p.H1119= (on ENST00000612955 / NM_001366650.1; = p.H98= on NM_015233.6) | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as rs1185308462; called by muse, mutect2, varscan2
- MYH11 | c.534C>T p.G178= | Silent (SNP) | VAF 45/168 reads (27%) | catalogued as rs764984716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.7002T>G p.G2334= (on ENST00000358273 / NM_001042492.3; = p.G2313= on NM_000267.3) | Silent (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- PKD1 | c.1185C>T p.G395= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs551865749; called by mutect2, varscan2
- PLXNB2 | c.951C>T p.D317= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs767853611; called by muse, mutect2, varscan2
- PRDM9 | c.1233C>T p.H411= | Silent (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1143C>T p.H381= (on ENST00000352766; = p.H302= on NM_181334.5) | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs368897846, COSV61232439; called by muse, mutect2, varscan2
- PRRC2B | c.867G>A p.P289= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs775664587; called by muse, mutect2, varscan2
- RFTN1 | c.772C>T p.L258= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- SGK1 | c.637C>T p.L213= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs746494763, COSV52808641, COSV52812191, COSV99398588; called by muse, mutect2, varscan2
- SOWAHB | c.63G>A p.V21= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- SOX15 | c.309G>A p.K103= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- TENM1 | c.729T>C p.H243= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- TENM4 | c.6726C>T p.R2242= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs1034671035; called by muse, mutect2, varscan2
- TTC9 | c.252G>A p.L84= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- WTAP | c.1185T>C p.V395= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- CLCN7 | c.981+15A>G | Intron (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- DSCR4 | n.109T>C | RNA (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PFKFB3 | c.-9G>A | 5'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- PIGQ | c.1532-587G>A | Intron (SNP) | VAF 40/98 reads (41%) | catalogued as rs745593701; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18560T>A | Intron (SNP) | VAF 39/154 reads (25%) | called by muse, varscan2
